Somatic mutation profile of tumor specimen TCGA-CZ-5456-01A (aliquot TCGA-CZ-5456-01A-01D-1501-10) from TCGA case TCGA-CZ-5456, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 57.9 years (21,164 days).
Specimen TCGA-CZ-5456-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3274c76a-eb06-47c2-a7af-ed1e425e6aed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5456-11A (Solid Tissue Normal), aliquot TCGA-CZ-5456-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68be1815-76d5-4429-8bc8-4160e4b27926

The open-access MAF lists 59 somatic variants for this specimen: 51 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 39, Silent 8, Frame Shift Del 7, Nonsense Mutation 3, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 82/248 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADRA1A | c.227C>G p.T76S | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV52370499; called by muse, mutect2, varscan2
- ARNT2 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV57588639; called by muse, mutect2, varscan2
- ATP1A2 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV63405093; called by muse, mutect2, varscan2
- CAMTA1 | c.3307C>T p.P1103S | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1407055330, COSV57917310; called by muse, mutect2, varscan2
- CASP1 | c.1093G>T p.D365Y (on ENST00000436863 / NM_033292.4; = p.D344Y on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as COSV52830594; called by muse, mutect2, varscan2
- CD2AP | c.1309T>A p.F437I | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV63762071; called by muse, mutect2, varscan2
- CLMN | c.1814T>C p.L605P | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as COSV54186062; called by muse, mutect2, varscan2
- CLYBL | c.954G>A p.M318I | Missense Mutation (SNP) | VAF 66/383 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59226011; called by muse, mutect2, varscan2
- COL1A2 | c.2353A>G p.M785V | Missense Mutation (SNP) | VAF 209/546 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs770839335, COSV51962926; called by muse, mutect2, varscan2
- DENND5A | c.3845T>C p.V1282A | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV60236542; called by muse, mutect2, varscan2
- EPHB6 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs779680824, COSV67420118; called by muse, mutect2, varscan2
- FLG | c.3766C>A p.Q1256K | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as rs751147313, CM103730, COSV64240910; called by muse, mutect2, varscan2
- GPM6A | c.700del p.V234Ffs*9 | Frame Shift Del (DEL) | VAF 42/138 reads (30%) | catalogued as COSV54551053; called by mutect2, pindel, varscan2
- KIF1A | c.693C>G p.D231E | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV57491129, COSV57496549; called by muse, mutect2, varscan2
- KMT2B | c.5393C>G p.A1798G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV55866054; called by muse, mutect2, varscan2
- MRPL4 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53449268; called by muse, varscan2
- NOTCH2 | c.7300T>C p.S2434P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56699921; called by muse, varscan2
- PARN | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 163/484 reads (34%) | catalogued as COSV58369086; called by muse, mutect2, varscan2
- PASD1 | c.2062G>T p.D688Y | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64856769; called by muse, mutect2, varscan2
- PCDHB9 | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.191); catalogued as COSV53381865; called by muse, varscan2
- PDE11A | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1474341575, COSV53703251; called by muse, mutect2, varscan2
- PENK | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV59240662, COSV59242614; called by muse, mutect2, varscan2
- PHYH | c.741C>A p.H247Q | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53817392; called by muse, mutect2, varscan2
- PIF1 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs201996206, COSV51423628; called by muse, mutect2, varscan2
- PRRX1 | c.424T>C p.F142L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53417051, COSV99509340; called by muse, mutect2
- PTPDC1 | c.1790T>A p.L597Q (on ENST00000375360 / NM_177995.3; = p.L649Q on NM_152422.4) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56625181; called by muse, mutect2, varscan2
- RAB33A | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57062914; called by muse, mutect2, varscan2
- RRS1 | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV52557803; called by muse, mutect2, varscan2
- SCUBE2 | c.545A>T p.H182L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV58545385; called by muse, mutect2, varscan2
- SELE | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60976973; called by muse, mutect2, varscan2
- SETD2 | c.1853C>G p.S618* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as rs750437096, COSV57430858; called by muse, mutect2, varscan2
- SETX | c.4826G>T p.G1609V | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as COSV56390706; called by muse, mutect2, varscan2
- SH3RF1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV52923537; called by muse, mutect2, varscan2
- SLC7A3 | c.983T>G p.I328S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV53228763; called by muse, mutect2
- SLCO1C1 | c.1435A>T p.R479* | Nonsense Mutation (SNP) | VAF 34/535 reads (6%) | catalogued as COSV56877051; called by muse, mutect2
- SLCO4A1 | c.1643A>T p.Y548F | Missense Mutation (SNP) | VAF 225/604 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV53892689; called by muse, mutect2, varscan2
- SPDL1 | c.1311A>C p.K437N | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54669029; called by muse, mutect2, varscan2
- SRP72 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 144/449 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV61378659; called by muse, mutect2, varscan2
- TMEM59 | c.479G>A p.S160N | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV52375186; called by muse, mutect2, varscan2
- YBX3 | c.1050A>T p.K350N | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54386496; called by muse, mutect2, varscan2
- ZNF331 | c.447T>G p.H149Q | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53478723; called by muse, mutect2, varscan2
- ACSBG1 | c.658del p.L220* | Frame Shift Del (DEL) | VAF 36/113 reads (32%) | called by mutect2, pindel, varscan2
- DDX3X | c.915dup p.G306Wfs*42 (on ENST00000399959; = p.G307Wfs*42 on NM_001356.5) | Frame Shift Ins (INS) | VAF 296/593 reads (50%) | called by mutect2, pindel, varscan2
- EPC1 | c.450_456del p.G151Sfs*12 | Frame Shift Del (DEL) | VAF 74/262 reads (28%) | called by mutect2, pindel, varscan2
- IFT20 | c.327_331del p.E110* (on ENST00000395418 / NM_001267776.2; = p.E136* on NM_001267774.2) | Frame Shift Del (DEL) | VAF 50/369 reads (14%) | called by mutect2, pindel, varscan2
- MKLN1 | c.1096del p.I366Lfs*9 | Frame Shift Del (DEL) | VAF 114/514 reads (22%) | called by mutect2, pindel, varscan2
- PBRM1 | c.4531del p.Q1511Sfs*28 (on ENST00000296302 / NM_001366071.2; = p.Q1404Sfs*28 on NM_018313.5) | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- WDFY3 | c.1742del p.K581Sfs*10 | Frame Shift Del (DEL) | VAF 29/140 reads (21%) | called by mutect2, pindel, varscan2
- ZEB2 | c.2888G>A p.G963E | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ZNF704 | c.679_687del p.Y227_D229del | In Frame Del (DEL) | VAF 38/132 reads (29%) | called by mutect2, pindel
- CACNA1D | c.2892G>T p.G964= (on ENST00000350061 / NM_001128840.3; = p.G984= on NM_000720.4) | Silent (SNP) | VAF 255/569 reads (45%) | catalogued as COSV55458307; called by muse, mutect2, varscan2
- CHD7 | c.5106C>T p.S1702= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV71113203; called by muse, mutect2, varscan2
- COL4A2 | c.3549T>C p.A1183= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV64631688; called by muse, mutect2, varscan2
- MAML1 | c.2985C>G p.S995= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV52987762; called by muse, mutect2, varscan2
- POT1 | c.786G>A p.E262= | Silent (SNP) | VAF 253/693 reads (37%) | catalogued as COSV62932966; called by muse, mutect2, varscan2
- SAFB2 | c.588G>A p.L196= | Silent (SNP) | VAF 83/364 reads (23%) | catalogued as COSV53044173; called by muse, mutect2, varscan2
- SLC7A2 | c.984G>A p.A328= (on ENST00000494857 / NM_001370338.1; = p.A368= on NM_003046.6) | Silent (SNP) | VAF 161/443 reads (36%) | catalogued as rs573592866, COSV50250218; called by muse, mutect2, varscan2
- TMEM59 | c.480C>T p.S160= | Silent (SNP) | VAF 58/207 reads (28%) | catalogued as COSV52375174; called by muse, mutect2, varscan2
